CPTAC case C3N-02789 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4d6794c9-25bc-47a0-ac2e-352d434b577c

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1955; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Corpus uteri; Age at diagnosis: 61.9 years (22,610 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M1; AJCC pathologic T: T1a; AJCC pathologic N: N0; AJCC pathologic M: M1; AJCC pathologic stage: Stage II; FIGO stage: Stage II; Tumor grade: G2; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 1,683 days (4.6 years); Progression or recurrence: no; Days to last follow up: 1,683 days (4.6 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3.5 cm (a second GDC size field records 2.3 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 17; Margin status: Indeterminate.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (6 entries)
- Days to follow up: 285 days; Disease response: Tumor Free.
- Days to follow up: 725 days (2.0 years); Disease response: Tumor Free.
- Days to follow up: 1,137 days (3.1 years); Disease response: Tumor Free.
- Days to follow up: 1,432 days (3.9 years); Disease response: Tumor Free.
- Days to follow up: 1,432 days (3.9 years); Disease response: Complete Response.
- Days to follow up: 1,683 days (4.6 years); Disease response: Tumor Free.

Other clinical attributes
- Weight: 55.79 kg; Height: 147.32 cm; BMI: 25.7; Hormonal contraceptive use: Former User.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 0.1; Cigarettes per day: 2; Tobacco smoking onset year: 1975; Tobacco smoking quit year: 1976; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 1.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-02789-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 30 days; Initial weight: 252 mg; Time between excision and freezing: 27 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02789-21: Section location: Entire Cavity; Percent tumor nuclei: 85; Percent necrosis: 0.
- Sample C3N-02789-11: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 30 days; Time between excision and freezing: 27 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-02789-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 30 days; Method of sample procurement: Blood Draw.
